Somatic mutation profile of tumor specimen TCGA-61-2610-02A (aliquot TCGA-61-2610-02A-01W-1092-09) from TCGA case TCGA-61-2610, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.5 years (22,481 days).
Specimen TCGA-61-2610-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be12d8b9-47d0-4671-b5f7-61b89e9f166c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2610-11A (Solid Tissue Normal), aliquot TCGA-61-2610-11A-01W-1092-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ef1cf9-b34b-4868-a90a-124bd821370d

The open-access MAF lists 85 somatic variants for this specimen: 69 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.675del p.G226Afs*21 | Frame Shift Del (DEL) | VAF 68/118 reads (58%) | catalogued as rs1567550076, COSV52891821; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AMPD1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 129/356 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.67); catalogued as COSV62418762; called by muse, mutect2, varscan2
- ARID1A | c.5296G>T p.E1766* | Nonsense Mutation (SNP) | VAF 82/91 reads (90%) | catalogued as COSV61378533; called by muse, mutect2, varscan2
- ASB12 | c.464T>A p.L155Q | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62857696; called by muse, mutect2, varscan2
- BAZ2B | c.4727C>A p.A1576D | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV100600969; called by muse, mutect2
- BCL2L13 | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 52/142 reads (37%) | catalogued as COSV58227488, COSV58227580; called by muse, mutect2, varscan2
- CACNA2D2 | c.3028G>C p.E1010Q (on ENST00000479441 / NM_001174051.3; = p.E1003Q on NM_006030.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV99818303; called by muse, mutect2
- CCDC180 | c.1668A>T p.E556D | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV63834958; called by muse, mutect2, varscan2
- CCDC88C | c.1611G>T p.E537D | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as COSV66241414; called by muse, mutect2, varscan2
- CD96 | c.1486G>A p.A496T (on ENST00000283285 / NM_198196.3; = p.A480T on NM_005816.5) | Missense Mutation (SNP) | VAF 81/392 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as COSV51922424; called by muse, mutect2, varscan2
- CDRT1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63054279; called by muse, mutect2, varscan2
- CMYA5 | c.5655C>G p.F1885L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV71407414, COSV71409273; called by muse, mutect2, varscan2
- CNTN1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 134/359 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61644748; called by muse, mutect2, varscan2
- CNTRL | c.4780C>G p.Q1594E | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as COSV53053111; called by muse, mutect2, varscan2
- COL11A1 | c.3988G>T p.G1330C | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559885800, COSV62173038, COSV62174034; called by muse, varscan2
- CTNS | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV50443853; called by muse, mutect2, varscan2
- DCAF6 | c.2061C>G p.F687L (on ENST00000312263 / NM_001349778.1; = p.F707L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100394806; called by muse, mutect2
- DDX5 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV99858249; called by muse, mutect2
- EDA | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.403); catalogued as COSV65784648; called by muse, mutect2, varscan2
- FAM171A1 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs753162558, COSV65319319; called by muse, mutect2, varscan2
- FCHSD1 | c.1584C>A p.D528E | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV99781513; called by muse, mutect2
- FZD7 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV53811240, COSV53811420; called by muse, mutect2, varscan2
- GTF3C5 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100565553; called by muse, varscan2
- HECTD4 | c.2329T>G p.L777V | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61181428; called by muse, mutect2, varscan2
- HIVEP1 | c.7478T>A p.M2493K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV65104837; called by muse, mutect2, varscan2
- IFT172 | c.4978C>A p.Q1660K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV51995810; called by muse, mutect2, varscan2
- IRAG1 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373906826; called by muse, mutect2, varscan2
- KAT6B | c.4680G>T p.Q1560H | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54754139; called by muse, mutect2, varscan2
- KRTAP22-1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 101/224 reads (45%) | PolyPhen probably damaging (0.969); catalogued as COSV58182958; called by muse, mutect2, varscan2
- LINGO2 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100430456, COSV58064003; called by muse, mutect2, varscan2
- LPAR4 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1318063081, COSV70913376; called by muse, mutect2, varscan2
- LRRC7 | c.1583G>A p.R528H (on ENST00000651989 / NM_001370785.2; = p.R495H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs750231315, COSV50488265; called by muse, mutect2, varscan2
- MADD | c.4222G>T p.V1408L | Missense Mutation (SNP) | VAF 99/160 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100211939, COSV60621922; called by muse, mutect2, varscan2
- MROH5 | c.1940G>T p.R647M | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV71302806; called by muse, mutect2, varscan2
- MRPL2 | c.521-1G>A p.X174_splice | Splice Site (SNP) | VAF 101/327 reads (31%) | catalogued as COSV52439085; called by muse, mutect2, varscan2
- MSANTD3-TMEFF1 | c.38dup p.E14Gfs*21 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs756460439; called by mutect2, pindel
- MUC4 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 634/1128 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.413); catalogued as COSV62190376; called by muse, mutect2, varscan2
- MYBPC1 | c.1018C>G p.P340A (on ENST00000550270 / NM_206820.2; = p.P365A on NM_002465.4) | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV100638259; called by muse, mutect2
- NCEH1 | c.389C>T p.P130L (on ENST00000538775; = p.P98L on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1337587456, COSV56438009; called by muse, mutect2, varscan2
- NOX1 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 851/1790 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54196464; called by muse, mutect2, varscan2
- OR8S1 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 203/542 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59600822; called by muse, mutect2, varscan2
- PHAX | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV52552410; called by muse, mutect2, varscan2
- PHLPP1 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.071); catalogued as rs376292612; called by muse, mutect2, varscan2
- RABGAP1L | c.1281C>G p.S427R | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52326928; called by muse, mutect2, varscan2
- RAVER2 | c.2010C>G p.D670E (on ENST00000294428 / NM_001366165.1; = p.D657E on NM_018211.4) | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV53810684; called by muse, mutect2, varscan2
- RBSN | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV53795472; called by muse, mutect2, varscan2
- RICTOR | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57123916; called by muse, mutect2, varscan2
- SGCA | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs749376128, COSV56251016; called by muse, mutect2, varscan2
- SKAP2 | c.9C>G p.N3K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.014); catalogued as COSV100592124; called by muse, mutect2
- SLX4 | c.2912A>G p.E971G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1017782828, COSV53568269; called by muse, mutect2, varscan2
- SPEN | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65367208; called by muse, mutect2, varscan2
- SYK | c.1182-1G>C p.X394_splice | Splice Site (SNP) | VAF 58/72 reads (81%) | catalogued as COSV65330229; called by muse, mutect2, varscan2
- SYT1 | c.244A>T p.K82* | Nonsense Mutation (SNP) | VAF 208/457 reads (46%) | catalogued as COSV54072067; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99305492; called by muse, mutect2
- TMTC3 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 99/360 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.358); catalogued as COSV57126224; called by muse, mutect2, varscan2
- TRMT1L | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62273364; called by muse, mutect2, varscan2
- TRPC7 | c.1262T>A p.F421Y | Missense Mutation (SNP) | VAF 224/725 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.024); catalogued as COSV61463290; called by muse, mutect2, varscan2
- TTC33 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV100532094; called by muse, mutect2
- USP37 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 190/446 reads (43%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.91); catalogued as COSV51447052; called by muse, mutect2, varscan2
- VPS35L | c.742C>G p.R248G | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99221653; called by muse, mutect2
- ZP1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV53926838; called by muse, mutect2, varscan2
- CCNF | c.2257_2258del p.P753Kfs*22 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- CYP3A7 | c.1224_1234del p.W408* | Nonsense Mutation (DEL) | VAF 69/196 reads (35%) | called by mutect2, pindel, varscan2
- DOCK9 | c.4715_4718del p.T1572Kfs*7 (on ENST00000376460 / NM_001366676.2; = p.T1573Kfs*7 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- IRF1 | c.509_519del p.M170Rfs*35 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- SHANK2 | c.1932del p.A646Lfs*34 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- ZDHHC15 | c.908_920del p.S303Cfs*2 | Frame Shift Del (DEL) | VAF 171/654 reads (26%) | called by mutect2, pindel, varscan2
- ZNF770 | c.1493_1528del p.T498_G509del | In Frame Del (DEL) | VAF 19/32 reads (59%) | called by mutect2, pindel
- BRD8 | c.1566C>T p.A522= (on ENST00000254900 / NM_139199.2; = p.A595= on NM_006696.4) | Silent (SNP) | VAF 75/267 reads (28%) | catalogued as rs766077957, COSV50167538; called by muse, mutect2, varscan2
- GGA3 | c.2028C>T p.I676= (on ENST00000537686 / NM_138619.4; = p.I643= on NM_014001.5) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99822329; called by muse, mutect2
- KIAA1210 | c.3132T>A p.T1044= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV68179949; called by muse, mutect2, varscan2
- MAGEC1 | c.303T>C p.S101= | Silent (SNP) | VAF 101/359 reads (28%) | catalogued as COSV53580704; called by muse, mutect2, varscan2
- MMP16 | c.54G>T p.S18= | Silent (SNP) | VAF 28/564 reads (5%) | catalogued as COSV54151279; called by muse, mutect2
- MTR | c.2892T>C p.Y964= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as rs746625029, COSV63966262; called by muse, mutect2, varscan2
- PBXIP1 | c.201C>T p.S67= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs1464302559, COSV63777675; called by muse, mutect2, varscan2
- PLA2G2D | c.24G>C p.G8= | Silent (SNP) | VAF 51/284 reads (18%) | catalogued as COSV64282101; called by muse, mutect2, varscan2
- PLEC | c.12708C>T p.L4236= (on ENST00000322810 / NM_201380.4; = p.L4126= on NM_000445.5) | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV59692257; called by muse, mutect2, varscan2
- QTRT2 | c.1101G>A p.L367= | Silent (SNP) | VAF 627/1469 reads (43%) | catalogued as COSV55561675; called by muse, mutect2, varscan2
- RADX | c.438G>T p.G146= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as COSV65320020, COSV65320396; called by muse, mutect2, varscan2
- TESMIN | c.1318A>C p.R440= | Silent (SNP) | VAF 87/201 reads (43%) | catalogued as COSV54834986; called by muse, mutect2, varscan2
- TMEM63A | c.1107C>A p.A369= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100834446; called by muse, mutect2
- ZNF226 | c.2256G>A p.E752= | Silent (SNP) | VAF 207/287 reads (72%) | catalogued as COSV56197910; called by muse, mutect2, varscan2
- ZNF70 | c.1218C>T p.L406= | Silent (SNP) | VAF 98/256 reads (38%) | catalogued as COSV100558946; called by muse, mutect2
- FOLH1B | n.1638G>T | RNA (SNP) | VAF 164/259 reads (63%) | called by muse, mutect2, varscan2
